Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A45C, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A45C-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

PART 1: THYROID, TOTAL THYROIDECTOMY (39 GRAMS) -

- PAPILLARY THYROID CARCINOMA, THREE (3) FOCI (1.0 CM, 0.2 CM AND 0.1 CM), LEFT LOBE, NO ANGIOLYMPHATIC INVASION.
- LARGEST FOCUS, CONVENTIONAL TYPE WITH MICROSCOPIC EXTRATHYROIDAL EXTENSION; MARGINS FREE (CLOSEST 0.1 CM).
- PATHOLOGIC STAGE: pT3 N0.
- NODULAR THYROID HYPERPLASIA.

PART 2: LYMPH NODES, CENTRAL COMPARTMENT, SELECTIVE DISSECTION -

- TWO (2) LYMPH NODES, NO TUMOR PRESENT (0/2).
- NORMOCELLULAR PARATHYROID.
- TISSUE ENTIRELY SUBMITTED FOR HISTOLOGIC EVALUATION.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY THYROID TUMORS

SPECIMEN TYPE:	Total Thyroidectomy
TUMOR SITE:	Left Lobe
TUMOR FOCALITY:	Multifocal
TUMOR SIZE (largest nodule):	Greatest Dimension: 1.0 cm
HISTOLOGIC TYPE**:	Papillary carcinoma
PRIMARY TUMOR (pT):	pT3
REGIONAL LYMPH NODES (pN):	pN0
	Number of regional lymph nodes examined: 2
	Number of regional lymph nodes involved: 0
DISTANT METASTASIS (pM):	Not applicable
EXTRATHYROIDAL EXTENSION:	Present
	Extent: Minimal
MARGINS:	Margins uninvolved by carcinoma
	Distance of invasive carcinoma to closest margin: 1 mm
LYMPH-VASCULAR INVASION:	Not identified
ADDITIONAL PATHOLOGIC FINDINGS:	Nodular goiter

ICD-O-3

Carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

pw
9/29/12

HRPA Discrepancy		☒

Source: NCI Genomic Data Commons file 80e3c981-4db2-478b-8f90-54fd53909d9e (TCGA-BJ-A45C.E30E5257-7791-4393-9CF2-5B59916FA846.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).